Somatic mutation profile of tumor specimen TCGA-HD-7229-01A (aliquot TCGA-HD-7229-01A-11D-2012-08) from TCGA case TCGA-HD-7229, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.4 years (22,076 days).
Specimen TCGA-HD-7229-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43027e1e-f4cb-4524-83a0-f3d089fc8d89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-7229-10A (Blood Derived Normal), aliquot TCGA-HD-7229-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49a54ea2-a393-4050-9ee7-6b7c9953e868

The open-access MAF lists 158 somatic variants for this specimen: 125 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 32, Nonsense Mutation 8, Frame Shift Del 5, Splice Region 2, In Frame Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as rs397514628, CM1211999, COSV100938153, COSV65040077, COSV65043006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 35/65 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.1455C>G p.D485E (on ENST00000295851 / NM_001375719.1; = p.D447E on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as COSV99651611; called by muse, mutect2, varscan2
- ADGRF1 | c.1903T>G p.L635V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99347089; called by muse, mutect2, varscan2
- AGPAT4 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100211115; called by muse, mutect2, varscan2
- AKAP9 | c.1538A>T p.K513M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100662113; called by muse, mutect2, varscan2
- AP5B1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as rs1383201296, COSV100375941; called by muse, mutect2
- ARHGAP45 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs769720722, COSV53124512, COSV53125334; called by muse, mutect2, varscan2
- ATP6V1G2 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as COSV100385378; called by muse, mutect2, varscan2
- ATXN2 | c.768G>T p.T256= (on ENST00000550104; = p.T96= on NM_002973.4) | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101112637; called by muse, mutect2, varscan2
- C1QC | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs776530672, COSV65890095; called by muse, mutect2, varscan2
- CCAR1 | c.2792A>G p.Y931C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99770785; called by muse, mutect2, varscan2
- CCDC185 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64821970; called by muse, mutect2
- CCDC88B | c.806G>C p.R269P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100105170; called by muse, mutect2, varscan2
- CDH18 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV56921680, COSV56931790, COSV99932997; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1385G>C p.R462P (on ENST00000357886 / NM_001365728.1; = p.R448P on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100211949, COSV59426976; called by muse, mutect2, varscan2
- CDYL2 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV101629523; called by muse, mutect2, varscan2
- CHMP1B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV99303224; called by muse, mutect2, varscan2
- CKAP5 | c.6060G>C p.L2020F (on ENST00000529230 / NM_001008938.4; = p.L1960F on NM_014756.3) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100319403; called by muse, mutect2, varscan2
- CLDN18 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs772493450, COSV59302428, COSV59302939; called by muse, mutect2, varscan2
- CLEC4M | c.840C>G p.Y280* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99940432; called by muse, mutect2, varscan2
- COL4A2 | c.893T>A p.M298K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.227); catalogued as COSV100847282; called by muse, mutect2, varscan2
- CSNK1E | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs775283367, COSV63291416; called by muse, mutect2, varscan2
- CXorf58 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101002949; called by muse, mutect2, varscan2
- DCANP1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs752321523, COSV101538227; called by muse, mutect2
- DCHS1 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV100201760; called by muse, mutect2, varscan2
- DDI1 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1355603865, COSV100158372; called by muse, mutect2, varscan2
- DLAT | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99734536; called by muse, mutect2, varscan2
- DPH1 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs367898997; called by muse, mutect2, varscan2
- DSP | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs139582608, COSV65795250; called by muse, mutect2, varscan2
- DYNC2I2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs11541003, COSV100823358; called by muse, mutect2, varscan2
- ENOX2 | c.1332A>C p.R444S (on ENST00000338144 / NM_001382520.1; = p.R415S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/152 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100583920; called by muse, mutect2, varscan2
- ESF1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.026); catalogued as COSV52520261, COSV99176294; called by muse, mutect2, varscan2
- EVC2 | c.2970C>G p.S990R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100185387; called by muse, mutect2, varscan2
- FAM135B | c.3131T>A p.F1044Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV52734565, COSV52750348; called by muse, mutect2, varscan2
- FBXO17 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.845); catalogued as COSV99494018; called by muse, mutect2, varscan2
- GABRB3 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV100158920; called by muse, mutect2, varscan2
- GBP4 | c.1853T>C p.M618T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100864331; called by muse, mutect2, varscan2
- GGA2 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100564591, COSV59170068; called by muse, mutect2, varscan2
- GIMAP1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100212015; called by muse, mutect2, varscan2
- GPR31 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100834110; called by muse, mutect2, varscan2
- GPX4 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100684235; called by muse, mutect2, varscan2
- GRK2 | c.564G>C p.M188I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100419598; called by muse, mutect2, varscan2
- GUCY1B1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100025397; called by muse, mutect2, varscan2
- GYPA | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752168013, COSV99301346; called by muse, mutect2, varscan2
- H1-5 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58900540; called by muse, mutect2, varscan2
- HIRA | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.184); catalogued as rs771778888, COSV99600057; called by muse, mutect2, varscan2
- HIVEP3 | c.5665G>A p.A1889T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1286378833, COSV99911918; called by muse, mutect2, varscan2
- HYOU1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs782770261, COSV68215170; called by muse, mutect2, varscan2
- IGKV1D-16 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs774987960; called by muse, mutect2, varscan2
- JARID2 | c.3540G>C p.L1180F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV100521558; called by muse, mutect2, varscan2
- KAT5 | c.1388A>C p.N463T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100383862; called by muse, mutect2, varscan2
- KMT2C | c.1908T>G p.H636Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100069125; called by muse, mutect2, varscan2
- KNG1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99405316; called by muse, mutect2, varscan2
- KRT1 | c.1813G>T p.G605C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99358567; called by muse, mutect2
- KRTAP5-2 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101295069; called by muse, mutect2, varscan2
- KSR2 | c.2227A>G p.K743E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100194448; called by muse, mutect2, varscan2
- L3MBTL2 | c.2041G>T p.V681L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99345756; called by muse, mutect2, varscan2
- LAMA2 | c.3830G>C p.R1277P | Missense Mutation (SNP) | VAF 147/223 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101370247, COSV70342133; called by muse, mutect2, varscan2
- LARGE2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771057944, COSV99138209; called by muse, mutect2, varscan2
- LRP1B | c.5336A>C p.K1779T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101254239; called by muse, mutect2, varscan2
- LRRC37A3 | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs1472491632, COSV100140938; called by muse, mutect2, varscan2
- LRRC56 | c.1136T>A p.F379Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV54239906, COSV99529741; called by muse, mutect2, varscan2
- LRRTM4 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101297466; called by muse, mutect2, varscan2
- MAPT | c.920C>A p.S307Y (on ENST00000262410 / NM_001377265.1; = p.S232Y on NM_016835.4) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99290056; called by muse, mutect2, varscan2
- MBTPS1 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs761436859, COSV100597427; called by muse, mutect2, varscan2
- MDN1 | c.13015C>A p.L4339I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101020955; called by muse, mutect2, varscan2
- ME3 | c.228C>G p.H76Q | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV100042138, COSV60164582; called by muse, mutect2, varscan2
- MEST | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs782548896, COSV56227774; called by muse, mutect2, varscan2
- MGRN1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99273894, COSV99274013; called by muse, varscan2
- MIGA1 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372915680; called by muse, mutect2, varscan2
- MROH7 | c.3292G>C p.E1098Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV100273170; called by muse, mutect2, varscan2
- MYO5A | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62562580; called by muse, mutect2, varscan2
- NAV1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs143487790; called by muse, mutect2, varscan2
- NCEH1 | c.346G>C p.D116H (on ENST00000538775; = p.D84H on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56432381; called by muse, mutect2, varscan2
- NEK11 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs535090384, COSV104369386, COSV99393704; called by muse, mutect2, varscan2
- NMT1 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1208099201, COSV99364611; called by muse, mutect2, varscan2
- NOTCH3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV54632878; called by muse, mutect2, varscan2
- NPY1R | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1345171446, COSV99648582, COSV99649136; called by muse, mutect2, varscan2
- NUB1 | c.1696G>C p.E566Q (on ENST00000568733 / NM_001243351.1; = p.E552Q on NM_016118.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100561188; called by muse, mutect2, varscan2
- NUDT16L1 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99273896; called by muse, mutect2
- OR13C4 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99470055; called by muse, mutect2, varscan2
- OR4C15 | c.512T>A p.M171K (on ENST00000314644; = p.M117K on NM_001001920.2) | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV100115473; called by muse, mutect2, varscan2
- PCLO | c.6323del p.S2108* | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as COSV61652009; called by mutect2, pindel, varscan2
- PCTP | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479066158, COSV99273722; called by muse, mutect2, varscan2
- PHRF1 | c.4865C>T p.A1622V (on ENST00000264555 / NM_001286581.2; = p.A1621V on NM_020901.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52756665, COSV99199700; called by muse, mutect2
- PLA2G2D | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV100908005; called by muse, mutect2, varscan2
- PLCB3 | c.3365C>G p.T1122R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.24); catalogued as rs575846795, COSV54189114, COSV54189320, COSV54190771; called by muse, mutect2, varscan2
- PLD5 | c.805C>G p.L269V (on ENST00000442594; = p.L207V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.433); catalogued as COSV100139461, COSV59154464; called by muse, mutect2, varscan2
- POSTN | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1355991815, COSV101123278; called by muse, mutect2, varscan2
- PPFIA2 | c.3641G>T p.G1214V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as COSV100332276; called by muse, mutect2, varscan2
- PRIM1 | c.102A>T p.G34= | Splice Region (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100590349; called by muse, mutect2, varscan2
- PRKCE | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100077198; called by muse, mutect2, varscan2
- PRKX | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV99467820; called by muse, mutect2, varscan2
- PTDSS1 | c.1048G>C p.V350L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); catalogued as COSV100428539, COSV100429013; called by muse, mutect2, varscan2
- RBM42 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99178062; called by muse, mutect2, varscan2
- RFX6 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100263483; called by muse, mutect2, varscan2
- RSPH4A | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99993991; called by muse, mutect2, varscan2
- SAAL1 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253788; called by muse, mutect2, varscan2
- SEPTIN1 | c.184C>G p.L62V (on ENST00000321367; = p.L15V on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV100363017; called by muse, mutect2, varscan2
- SHROOM3 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV99933831; called by muse, mutect2, varscan2
- SI | c.2443G>T p.G815* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52301385; called by muse, mutect2, varscan2
- SLC25A3 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99499043; called by muse, mutect2, varscan2
- SMTNL1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs1269122836, COSV101216280; called by muse, mutect2, varscan2
- SNX5 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100898989; called by muse, mutect2, varscan2
- SOBP | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100432926; called by muse, mutect2, varscan2
- SVEP1 | c.6559G>A p.E2187K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as rs759376529; called by muse, mutect2, varscan2
- SWAP70 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs200767479, COSV100013614; called by muse, mutect2
- SYNDIG1L | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100526425; called by muse, mutect2, varscan2
- TFPI | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99258288; called by muse, mutect2, varscan2
- TRIO | c.6153C>G p.H2051Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.227); catalogued as COSV100710069, COSV60079572; called by muse, mutect2, varscan2
- TUBA1B | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100254083; called by muse, mutect2, varscan2
- WNT10A | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51463384, COSV99297324; called by muse, mutect2, varscan2
- WWP2 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs762488499, COSV100598487; called by muse, mutect2, varscan2
- XIRP2 | c.3701G>A p.S1234N (on ENST00000628543; = p.S1409N on NM_152381.6) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99740269; called by mutect2, varscan2
- ZBBX | c.1276T>G p.C426G | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100283490, COSV56800324; called by muse, mutect2
- ZNF318 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs1440028156, COSV58931991; called by muse, mutect2, varscan2
- CELSR2 | c.406_408del p.P136del | In Frame Del (DEL) | VAF 27/86 reads (31%) | called by mutect2, pindel, varscan2
- MPP3 | c.767_768dup p.R257Afs*8 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by pindel, varscan2
- OR1S1 | c.643_650del p.V215Ifs*64 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PMAIP1 | c.66_69del p.V23Sfs*13 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- TMEM95 | c.391_392del p.R131Kfs*76 (on ENST00000576060 / NM_001320436.2; = p.R139Kfs*76 on NM_198154.3) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- TMTC3 | c.830del p.P277Lfs*5 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- TUBGCP3 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- ACTG1 | c.390G>T p.P130= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV100111881; called by muse, mutect2, varscan2
- ATP6V0D1 | c.210C>T p.I70= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs762823560, COSV52098042; called by muse, mutect2, varscan2
- CCDC144A | c.3153G>A p.L1051= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100138432; called by muse, mutect2, varscan2
- CCDC181 | c.1041A>G p.E347= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100890277; called by muse, mutect2, varscan2
- COL4A1 | c.2244C>T p.P748= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs755340790, COSV101011014, COSV65420928; called by muse, mutect2, varscan2
- COL5A3 | c.2637C>T p.F879= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1326400883, COSV53406832; called by muse, mutect2, varscan2
- DAPK2 | c.993G>A p.S331= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs201355789, COSV99977165; called by muse, mutect2, varscan2
- DNAH11 | c.2826G>T p.P942= | Silent (SNP) | VAF 46/67 reads (69%) | catalogued as COSV100178129; called by muse, mutect2, varscan2
- DNAJC5G | c.81C>A p.G27= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV56079563, COSV99940509; called by muse, varscan2
- DNM2 | c.1629T>C p.F543= (on ENST00000355667 / NM_001005360.3; = p.F539= on NM_004945.3) | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100116973; called by muse, mutect2
- EMSY | c.2874G>A p.P958= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs149047897, COSV58257508; called by muse, mutect2, varscan2
- ESRRG | c.1320A>G p.L440= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1387963614, COSV100752522; called by muse, mutect2, varscan2
- FAM83A | c.645C>T p.L215= | Silent (SNP) | VAF 38/217 reads (18%) | catalogued as COSV52688247; called by muse, mutect2, varscan2
- FBN2 | c.7155C>G p.L2385= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99324719, COSV99325869; called by muse, mutect2
- GCNA | c.558G>C p.S186= | Silent (SNP) | VAF 100/176 reads (57%) | catalogued as COSV101032450, COSV65465853; called by muse, mutect2, varscan2
- HCN4 | c.2187C>G p.L729= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs201156570, COSV99983448; called by muse, mutect2, varscan2
- HSPG2 | c.7011C>T p.A2337= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs150649767; called by muse, mutect2, varscan2
- KDF1 | c.1152C>T p.T384= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs368907239; called by muse, mutect2, varscan2
- MTMR2 | c.1653C>T p.F551= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV100334625; called by muse, mutect2, varscan2
- NEIL1 | c.204C>G p.P68= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100748511; called by muse, mutect2, varscan2
- NMUR1 | c.297C>G p.L99= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV59404122, COSV59404236; called by muse, mutect2, varscan2
- OGFOD1 | c.915G>A p.T305= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1339673471, COSV100272951; called by muse, mutect2, varscan2
- OR9G4 | c.108G>A p.L36= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100265057, COSV100265230; called by muse, mutect2, varscan2
- PCDH8 | c.351G>A p.R117= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100131351; called by muse, mutect2, varscan2
- PCDH9 | c.1470T>A p.T490= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100119278; called by muse, mutect2, varscan2
- PLEC | c.8091T>C p.H2697= (on ENST00000322810 / NM_201380.4; = p.H2587= on NM_000445.5) | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100512150; called by muse, mutect2, varscan2
- RINL | c.855C>T p.I285= (on ENST00000591812 / NM_001195833.2; = p.I171= on NM_198445.4) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV61574916; called by muse, mutect2, varscan2
- SPPL2C | c.1620C>T p.A540= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs140347532; called by muse, mutect2, varscan2
- THBS2 | c.1020G>C p.T340= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100827724, COSV64682409; called by muse, mutect2, varscan2
- TMEM181 | c.1389G>A p.S463= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs749776167, COSV100892502; called by muse, mutect2, varscan2
- VPS39 | c.1734G>A p.P578= (on ENST00000348544 / NM_001301138.2; = p.P567= on NM_015289.5) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs748127127, COSV100529043; called by muse, mutect2, varscan2
- ZGRF1 | c.5823A>T p.T1941= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101500578; called by muse, mutect2
- PKD1L2 | n.3183C>T | RNA (SNP) | VAF 5/23 reads (22%) | catalogued as rs780261089; called by muse, mutect2, varscan2
